Somatic mutation profile of tumor specimen TCGA-HC-A6AN-01A (aliquot TCGA-HC-A6AN-01A-11D-A30E-08) from TCGA case TCGA-HC-A6AN, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.6 years (24,697 days).
Specimen TCGA-HC-A6AN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6177a5d5-19dd-4884-b5d9-be7068a258ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-A6AN-10A (Blood Derived Normal), aliquot TCGA-HC-A6AN-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40db8684-c72f-4394-bfc9-87384895ab32

The open-access MAF lists 37 somatic variants for this specimen: 30 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 5, Intron 2, Nonsense Mutation 1, In Frame Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 6/116 reads (5%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, mutect2
- ALDH1L1 | c.1492C>A p.Q498K | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV56410119; called by muse, mutect2, varscan2
- ANKRD35 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.381); catalogued as COSV62909404; called by muse, mutect2, varscan2
- ANKRD6 | c.1828G>C p.A610P (on ENST00000339746 / NM_001242809.2; = p.A605P on NM_014942.4) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.113); catalogued as COSV60228412; called by muse, mutect2, varscan2
- COL6A3 | c.5456C>T p.A1819V | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs764242694, COSV55078430; called by muse, mutect2, varscan2
- DCC | c.637T>A p.S213T | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV59081437; called by muse, mutect2, varscan2
- FBN1 | c.7631C>T p.T2544I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57308157; called by muse, mutect2, varscan2
- ITPRID1 | c.2694C>A p.D898E | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV60069529; called by muse, mutect2, varscan2
- KCNA3 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 56/177 reads (32%) | catalogued as COSV63900826; called by muse, mutect2, varscan2
- KCNJ5 | c.800G>T p.R267L | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57962762, COSV57963635; called by muse, mutect2, varscan2
- KCNK9 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57277754, COSV57286913; called by muse, mutect2, varscan2
- KCNN1 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1167447504, COSV55839903; called by muse, mutect2, varscan2
- KDM3B | c.1006G>T p.D336Y | Missense Mutation (SNP) | VAF 54/268 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV58687382; called by muse, mutect2, varscan2
- MACF1 | c.20735G>A p.R6912Q (on ENST00000372915; = p.R4957Q on NM_012090.5) | Missense Mutation (SNP) | VAF 11/87 reads (13%) | catalogued as rs756134944, COSV57103765; called by muse, mutect2, varscan2
- NDUFB10 | c.225C>G p.D75E | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs779919042, COSV51909353; called by muse, mutect2, varscan2
- NEBL | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs548438161, COSV65799441; called by muse, mutect2, varscan2
- OR5P3 | c.845T>C p.I282T | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as rs773299212, COSV60428788; called by muse, mutect2, varscan2
- PDE6B | c.236T>C p.V79A | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV55323421; called by muse, mutect2, varscan2
- PRELID1 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.147); catalogued as rs1278033316, COSV57462787; called by muse, mutect2, varscan2
- RAP1GAP | c.1667C>G p.A556G | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.034); catalogued as COSV51568096; called by muse, mutect2, varscan2
- RO60 | c.986A>G p.E329G | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.31); catalogued as COSV66473116; called by muse, mutect2, varscan2
- SERPINB1 | c.756G>C p.L252F | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.184); catalogued as COSV66313565; called by muse, mutect2, varscan2
- SLC9A3 | c.1372C>A p.P458T | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53798543; called by muse, mutect2, varscan2
- TEKT1 | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV58621936; called by muse, mutect2, varscan2
- TNS1 | c.3307C>A p.P1103T | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV50690102; called by muse, mutect2
- VWF | c.5437G>T p.D1813Y | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.382); catalogued as COSV54610395; called by muse, mutect2, varscan2
- ZNF746 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.894); catalogued as rs147702038; called by muse, mutect2, varscan2
- ANXA8 | c.555T>A p.D185E | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FOXP1 | c.1054_1059dup p.E352_L353dup | In Frame Ins (INS) | VAF 12/60 reads (20%) | called by mutect2, varscan2
- REV3L | c.6779del p.P2260Hfs*13 | Frame Shift Del (DEL) | VAF 28/99 reads (28%) | called by mutect2, pindel, varscan2
- ADAP1 | c.786G>C p.T262= | Silent (SNP) | VAF 58/213 reads (27%) | catalogued as rs139452042, COSV56210435; called by muse, mutect2, varscan2
- FARSB | c.552G>A p.K184= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs769568733, COSV56047927, COSV99918602; called by muse, mutect2, varscan2
- MAGI2 | c.2934G>T p.V978= | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as COSV62631373; called by muse, mutect2, varscan2
- MFN2 | c.270G>A p.E90= | Silent (SNP) | VAF 100/411 reads (24%) | catalogued as COSV52420153; called by muse, mutect2, varscan2
- OR8B2 | c.585C>T p.N195= | Silent (SNP) | VAF 38/139 reads (27%) | catalogued as rs761030464, COSV66664104; called by muse, mutect2, varscan2
- GON4L | c.4473+40del | Intron (DEL) | VAF 23/84 reads (27%) | called by mutect2, pindel, varscan2
- MRC1 | c.917-146G>A | Intron (SNP) | VAF 27/78 reads (35%) | catalogued as COSV99519383; called by muse, mutect2, varscan2
